Gene-level copy-number profile of tumor specimen TCGA-DB-A4XF-01A from TCGA case TCGA-DB-A4XF, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Frontal lobe; Tumor grade: G3; Age at diagnosis: 41.2 years (15,066 days).
Specimen TCGA-DB-A4XF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.37a0cbef-735c-4159-b44c-51d23657ea14.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DB-A4XF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d297dfe9-e352-47d3-acb8-ba9cf1b61395

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 1,937; copy number 3: 1,292; copy number 4: 55,672; copy number 5: 3; copy number 6: 910.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DB-A4XF-01A-11D-A27J-01): tumor purity 0.84, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
